Somatic mutation profile of tumor specimen TCGA-2Y-A9H5-01A (aliquot TCGA-2Y-A9H5-01A-11D-A382-10) from TCGA case TCGA-2Y-A9H5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.7 years (21,818 days).
Specimen TCGA-2Y-A9H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27d058ed-0661-49be-8bf0-d7b0fa4209e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H5-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H5-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afe78c3e-9283-440c-b0d1-778e161e6097

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 2, Intron 2, Splice Site 2, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.6019C>T p.Q2007* | Nonsense Mutation (SNP) | VAF 12/87 reads (14%) | catalogued as rs1555395641, COSV100354273, COSV57309536; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ROR2 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as rs145631389; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs727503396, COSV63664819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- AGPAT5 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV99576350; called by muse, varscan2
- AHCTF1 | c.6520C>T p.Q2174* (on ENST00000366508; = p.Q2148* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 149/647 reads (23%) | catalogued as COSV58252032; called by muse, mutect2, varscan2
- ATP13A1 | c.3152A>G p.N1051S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs1457477879, COSV99179139; called by muse, mutect2, varscan2
- BRD9 | c.685A>T p.I229F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100057036; called by muse, mutect2, varscan2
- C5orf38 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | catalogued as rs371003626, COSV100121634, COSV57413466; called by muse, mutect2, varscan2
- CACNA1B | c.6980G>A p.R2327Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); catalogued as rs753876739, COSV99496093; called by muse, mutect2, varscan2
- CLASRP | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.14); catalogued as COSV99673694; called by muse, mutect2, varscan2
- CLEC7A | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100021082; called by muse, mutect2, varscan2
- COL27A1 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100620847; called by muse, mutect2
- CUL2 | c.1226A>G p.N409S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101039076; called by muse, mutect2, varscan2
- CYP21A2 | c.1285T>C p.C429R | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161362, COSV100926083; called by muse, mutect2, varscan2
- CYP4B1 | c.219G>T p.W73C | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99596940; called by muse, mutect2, varscan2
- DCSTAMP | c.194G>T p.W65L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99886310; called by muse, mutect2, varscan2
- DERA | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV70774090; called by muse, varscan2
- DIS3L2 | c.210G>A p.Q70= | Splice Region (SNP) | VAF 29/64 reads (45%) | catalogued as COSV56050116; called by muse, mutect2, varscan2
- DLG5 | c.5188C>T p.R1730W | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs775531975, COSV100967345; called by muse, mutect2, varscan2
- DMD | c.6434T>A p.L2145H | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100818748; called by muse, mutect2
- DUSP15 | c.416G>A p.S139N (on ENST00000278979 / NM_001320479.1; = p.S142N on NM_080611.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770925611, COSV99639598; called by muse, mutect2, varscan2
- EMB | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 120/390 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100296715; called by muse, mutect2, varscan2
- FANCI | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368127142; called by muse, mutect2, varscan2
- FCRL5 | c.1472C>T p.T491I | Missense Mutation (SNP) | VAF 116/208 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV100708712; called by muse, mutect2, varscan2
- GFRAL | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100474849; called by muse, mutect2, varscan2
- GIT1 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as rs374985717; called by muse, mutect2, varscan2
- GPAT3 | c.448A>T p.I150L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100022870; called by muse, mutect2, varscan2
- GZMB | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.093); catalogued as rs779606646, COSV99362266; called by muse, mutect2, varscan2
- H3C7 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV55099930; called by muse, mutect2
- HCCS | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1434929457, COSV100335644; called by muse, mutect2, varscan2
- HDAC6 | c.2318G>T p.R773L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100490683, COSV100491060; called by muse, mutect2, varscan2
- KCNA1 | c.923A>T p.H308L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101230169; called by muse, mutect2, varscan2
- KLHL38 | c.1366A>G p.R456G | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1563591884, COSV58089618; called by muse, mutect2, varscan2
- LHFPL6 | c.387C>G p.G129= | Splice Region (SNP) | VAF 27/55 reads (49%) | catalogued as COSV101095111; called by muse, mutect2, varscan2
- LRP1 | c.12991A>T p.T4331S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1373776309, COSV99675130; called by muse, mutect2, varscan2
- LRP1B | c.6799+1G>A p.X2267_splice | Splice Site (SNP) | VAF 34/68 reads (50%) | catalogued as COSV101254432, COSV101262135; called by muse, mutect2, varscan2
- NDST3 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as COSV99630004; called by muse, mutect2
- NEUROD1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99716849; called by muse, mutect2, varscan2
- NEXMIF | c.949T>G p.F317V | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99280196; called by muse, mutect2, varscan2
- NFATC2 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.145); catalogued as COSV101043818; called by muse, mutect2, varscan2
- NODAL | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99755393; called by muse, mutect2, varscan2
- NRCAM | c.155C>A p.S52Y (on ENST00000379028 / NM_001371124.1; = p.S46Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100694484; called by muse, mutect2, varscan2
- OR51F2 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100437960, COSV59066362; called by muse, mutect2, varscan2
- OR5AN1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100004316; called by muse, mutect2, varscan2
- PAMR1 | c.1507G>A p.A503T (on ENST00000619888 / NM_001001991.3; = p.A520T on NM_015430.4) | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99552336; called by muse, mutect2, varscan2
- PAQR3 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99784949; called by muse, mutect2, varscan2
- PGAP4 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs1470427127, COSV100877804; called by muse, mutect2, varscan2
- POGK | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV100902441; called by muse, mutect2, varscan2
- PREX2 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs751712561, COSV55748519, COSV99907655; called by muse, mutect2, varscan2
- PROSER1 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.085); catalogued as rs546645213, COSV100612714; called by muse, mutect2, varscan2
- RACGAP1 | c.1532A>G p.N511S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs758935582, COSV100407622; called by muse, mutect2, varscan2
- SLC10A7 | c.320+2T>A p.X107_splice | Splice Site (SNP) | VAF 49/123 reads (40%) | catalogued as COSV99390275; called by muse, mutect2, varscan2
- SLITRK4 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 121/371 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as rs376093373, COSV100567234, COSV100567367; called by muse, mutect2, varscan2
- SRFBP1 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs374380607; called by muse, mutect2, varscan2
- SRPK3 | c.1150C>G p.P384A | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99473029; called by muse, mutect2, varscan2
- TBX2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV99538733; called by muse, mutect2, varscan2
- TENM1 | c.6845A>C p.H2282P | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100949486; called by muse, mutect2, varscan2
- TLE1 | c.1852G>T p.G618* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV64719361, COSV64719460, COSV64723155; called by muse, mutect2, varscan2
- TMEM132D | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs781773967, COSV70621040; called by muse, mutect2, varscan2
- TRPC7 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1561733109, COSV61454469; called by muse, mutect2, varscan2
- XKRX | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 9/258 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV60707892; called by muse, mutect2
- ZNF804B | c.3406C>T p.H1136Y | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV100302659, COSV60836934; called by muse, mutect2, varscan2
- ACVR2A | c.619_622del p.W207Kfs*34 | Frame Shift Del (DEL) | VAF 65/149 reads (44%) | called by mutect2, pindel, varscan2
- CDH1 | c.2499dup p.D834* | Frame Shift Ins (INS) | VAF 25/77 reads (32%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ELF3 | c.184dup p.E62Gfs*30 | Frame Shift Ins (INS) | VAF 77/206 reads (37%) | called by mutect2, pindel, varscan2
- HOXB4 | c.397del p.H133Tfs*18 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- KLHDC7A | c.328del p.A110Pfs*93 | Frame Shift Del (DEL) | VAF 13/152 reads (9%) | called by mutect2, pindel
- LARP1B | c.119del p.S40Ifs*13 | Frame Shift Del (DEL) | VAF 52/398 reads (13%) | called by mutect2, pindel, varscan2
- VPS37B | c.25_33del p.R9_A11del | In Frame Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- ZNF800 | c.1262del p.P421Lfs*11 | Frame Shift Del (DEL) | VAF 56/154 reads (36%) | called by mutect2, varscan2
- ABHD13 | c.405A>G p.L135= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as rs752456357, COSV65535053; called by muse, mutect2, varscan2
- CACNA1G | c.6858C>T p.D2286= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV61732637; called by muse, mutect2, varscan2
- CDH8 | c.417G>C p.V139= | Silent (SNP) | VAF 74/124 reads (60%) | catalogued as COSV100180434; called by muse, mutect2, varscan2
- CEMIP2 | c.2718C>G p.S906= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100987084; called by muse, mutect2, varscan2
- CSMD2 | c.9540A>G p.G3180= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV99587678; called by muse, mutect2, varscan2
- DSCAM | c.2919C>T p.N973= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs200413358, COSV101259586; called by muse, mutect2, varscan2
- DSP | c.7986C>T p.H2662= | Silent (SNP) | VAF 61/233 reads (26%) | catalogued as rs753720770, COSV100672912; called by muse, mutect2, varscan2
- ESS2 | c.777C>G p.A259= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99350717; called by muse, mutect2, varscan2
- FGD3 | c.2007G>T p.G669= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100490465; called by muse, mutect2, varscan2
- LDHC | c.726C>T p.I242= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs1240785602, COSV99772387; called by muse, mutect2, varscan2
- LRRC4B | c.1521G>T p.R507= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100975872, COSV65350080; called by muse, mutect2, varscan2
- LRRC66 | c.1974C>T p.Y658= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV58631901; called by muse, mutect2, varscan2
- MALSU1 | c.24G>A p.A8= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV99799849; called by muse, mutect2
- MMP12 | c.402C>T p.I134= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV100404863; called by muse, mutect2, varscan2
- NEK6 | c.123G>A p.S41= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs766708819, COSV57221592; called by muse, mutect2, varscan2
- OR11A1 | c.423G>T p.R141= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV101010691; called by muse, mutect2, varscan2
- ROBO1 | c.2595G>A p.E865= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV101458428; called by muse, mutect2, varscan2
- SEC31A | c.265C>T p.L89= | Silent (SNP) | VAF 120/321 reads (37%) | catalogued as COSV100307082, COSV58882633; called by muse, mutect2, varscan2
- SLC1A4 | c.1542C>T p.N514= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV99308863; called by muse, mutect2
- ZNF18 | c.1197A>C p.P399= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100503066; called by muse, mutect2, varscan2
- NRG1 | c.700+665C>A | Intron (SNP) | VAF 22/48 reads (46%) | catalogued as COSV99828060; called by muse, mutect2, varscan2
- TRIB2 | c.563+1166del | Intron (DEL) | VAF 78/238 reads (33%) | called by mutect2, pindel, varscan2
